Gene-level copy-number profile of tumor specimen TCGA-KP-A3W1-01A from TCGA case TCGA-KP-A3W1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,902 days).
Specimen TCGA-KP-A3W1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.4600ba03-2e46-4737-b23d-e47aa72997cc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KP-A3W1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/507ca7d7-16ff-466c-b6f0-6d9302ab7418

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 1,543; copy number 3: 13,979; copy number 4: 20,898; copy number 5: 7,809; copy number 6: 5,345; copy number 7: 5,526; copy number 8: 2,636; copy number 9: 1,804; copy number 10: 80; copy number 11: 57; copy number 12: 79; copy number 17: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KP-A3W1-01A-11D-A227-01): tumor purity 0.34, ploidy 4.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,081 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,843,823–30,860,254, 2 genes, copy number 11: RN7SKP91, AL445235.1.
- chr1:153,357,854–153,946,718, 42 genes, copy number 10 (within-gene range 6–10): S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5, S100A4, S100A3, S100A2, BX470102.2, S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1, AL358472.5, DENND4B.
- chr2:36,299,388–36,656,941, 6 genes, copy number 9: RPL21P36, CRIM1-DT, CRIM1, AC007378.1, FEZ2, AC007363.1.
- chr2:119,302,225–119,700,151, 8 genes, copy number 10: C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15.
- chr2:240,713,761–241,095,568, 9 genes, copy number 9 (within-gene range 4–9): KIF1A, AGXT, MAB21L4, CROCC2, UICLM, AC104809.1, SNED1, AC093585.1, SNED1-AS1.
- chr3:47,346,950–47,580,792, 9 genes, copy number 10: AC104447.1, AC099778.1, PTPN23, SCAP, AC099778.2, ELP6, BOLA2P2, RN7SL870P, CSPG5.
- chr3:139,389,761–139,782,699, 1 gene, copy number 12 (within-gene range 7–12): AC046134.2.
- chr3:139,517,434–139,689,342, 7 genes, copy number 12: RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1.
- chr4:158,315,311–158,672,255, 5 genes, copy number 10 (within-gene range 4–10): RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46.
- chr6:33,572,547–33,711,727, 5 genes, copy number 9: BAK1, LINC00336, ITPR3, UQCC2, MIR3934.
- chr6:61,679,961–74,850,484, 137 genes, copy number 11–17 (within-gene range 5–17) (broad region; genes not listed).
- chr8:41,929,479–145,066,685, 1,591 genes, copy number 9 (broad region; genes not listed).
- chr22:36,226,209–36,703,752, 16 genes, copy number 10 (within-gene range 7–10): APOL2, APOL1, MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4.
- chr22:41,998,725–50,801,309, 243 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
